Somatic mutation profile of tumor specimen 0DUVUN from CCDI case PBCLRF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 4.0 years (1,462 days).
Specimen 0DUVUN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54fea6a6-f56a-4a33-bc9b-b8263c5b90d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUVT2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14f18d6a-058a-43fc-ab16-4f09c19b5746

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 3'UTR 3, Silent 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BPIFA3 | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 31/509 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.759); catalogued as COSV100967048; called by muse, mutect2
- CRISP1 | c.623C>T p.T208I | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100237140, COSV59992969, COSV59995583; called by muse, mutect2
- TNS3 | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 146/430 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs200656291; called by muse, mutect2, varscan2
- LRP2 | c.10579C>A p.P3527T | Missense Mutation (SNP) | VAF 25/426 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MORC4 | c.2064_2067dup p.P690Gfs*14 | Frame Shift Ins (INS) | VAF 108/329 reads (33%) | called by mutect2, varscan2
- RGS22 | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 216/641 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRO | c.1729A>T p.R577W | Missense Mutation (SNP) | VAF 127/375 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ZHX2 | c.2197G>A p.D733N | Missense Mutation (SNP) | VAF 19/320 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.494); called by muse, mutect2
- HDGFL1 | c.231G>A p.A77= | Silent (SNP) | VAF 23/248 reads (9%) | catalogued as rs1467805163, COSV100014478; called by muse, mutect2
- TRPM6 | c.5316A>G p.R1772= | Silent (SNP) | VAF 150/429 reads (35%) | called by muse, mutect2, varscan2
- ALPI | c.*33C>T | 3'UTR (SNP) | VAF 27/105 reads (26%) | called by muse, mutect2, varscan2
- ELOVL7 | c.-30C>A | 5'UTR (SNP) | VAF 150/437 reads (34%) | catalogued as COSV101415605; called by muse, mutect2, varscan2
- FAM135B | c.*4C>T | 3'UTR (SNP) | VAF 13/314 reads (4%) | called by muse, mutect2
- TNF | c.*28C>T | 3'UTR (SNP) | VAF 46/131 reads (35%) | catalogued as rs372252268; called by muse, mutect2, varscan2
